Somatic mutation profile of tumor specimen TCGA-MP-A4T7-01A (aliquot TCGA-MP-A4T7-01A-11D-A24P-08) from TCGA case TCGA-MP-A4T7, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.6 years (27,603 days).
Specimen TCGA-MP-A4T7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45f13e24-9fba-4f78-a0ce-7da6b2b852f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4T7-10A (Blood Derived Normal), aliquot TCGA-MP-A4T7-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/010ba621-7ec1-452e-9115-b7ec5f9b37d2

The open-access MAF lists 143 somatic variants for this specimen: 117 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 24, Nonsense Mutation 7, RNA 2, Splice Site 2, Frame Shift Del 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260583; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABHD13 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101024300; called by muse, mutect2, varscan2
- AC134980.2 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100171951; called by mutect2, varscan2
- ACAN | c.7485G>T p.R2495S (on ENST00000560601 / NM_001369268.1; = p.R2457S on NM_013227.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100613893; called by muse, mutect2, varscan2
- ACCSL | c.1294C>A p.Q432K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101122332; called by muse, mutect2, varscan2
- ALOXE3 | c.1175A>C p.K392T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100560053; called by muse, mutect2, varscan2
- ARHGEF6 | c.1787C>G p.P596R | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99166802; called by muse, mutect2, varscan2
- ASTN1 | c.851T>G p.M284R | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV99923378; called by muse, mutect2, varscan2
- ATF6 | c.1121C>G p.P374R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100909555; called by muse, mutect2, varscan2
- ATRNL1 | c.2098A>G p.M700V | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs782175957, COSV100747108; called by muse, mutect2, varscan2
- ATRNL1 | c.4121G>A p.R1374H | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.976); catalogued as rs182259056, COSV100373092; called by muse, mutect2, varscan2
- ATXN3L | c.742C>G p.R248G | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV101019623, COSV66075181; called by muse, mutect2, varscan2
- BCORL1 | c.5068G>T p.V1690L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV99501218; called by muse, varscan2
- BEND2 | c.1527G>T p.L509F | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101192279, COSV66216769; called by muse, mutect2, varscan2
- CABS1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.272); catalogued as COSV99909239; called by muse, mutect2, varscan2
- CEP128 | c.3095G>C p.G1032A | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.046); catalogued as COSV99826305; called by muse, mutect2
- CHIC1 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100998272, COSV65156572; called by muse, mutect2, varscan2
- CHST2 | c.1545G>C p.E515D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.16); catalogued as COSV100536190; called by muse, mutect2, varscan2
- CKAP5 | c.4858A>T p.N1620Y | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.58); catalogued as COSV100371576; called by muse, mutect2, varscan2
- CNTNAP2 | c.2049G>T p.E683D | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV100673730, COSV62149546; called by muse, mutect2, varscan2
- CNTRL | c.5277G>T p.Q1759H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99444169; called by muse, mutect2, varscan2
- COL17A1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755718830, COSV100793412; called by muse, mutect2, varscan2
- CTNNA1 | c.1161G>C p.M387I | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100243330; called by muse, mutect2, varscan2
- DHX57 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV54885894, COSV99770034; called by muse, mutect2
- EFS | c.1634T>A p.L545Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99249112; called by muse, mutect2, varscan2
- EGR4 | c.872C>A p.A291E (on ENST00000545030; = p.A188E on NM_001965.4) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV101474277; called by muse, mutect2, varscan2
- EID1 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs780651046, COSV100195509; called by muse, mutect2, varscan2
- ETV7 | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100339366, COSV60318146; called by muse, mutect2, varscan2
- FAM71A | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 38/187 reads (20%) | catalogued as COSV99674954; called by muse, mutect2, varscan2
- FHOD3 | c.3207C>A p.D1069E (on ENST00000359247 / NM_001281739.3; = p.D1086E on NM_025135.5) | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57172438, COSV99943365; called by muse, mutect2, varscan2
- FMO3 | c.1027A>T p.I343F | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV100882563; called by muse, mutect2, varscan2
- FNDC3A | c.2270G>T p.G757V (on ENST00000492622 / NM_001079673.2; = p.G701V on NM_014923.5) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV101257016; called by muse, mutect2, varscan2
- FOXO4 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as COSV100447089; called by muse, mutect2, varscan2
- GABRB1 | c.269A>C p.Q90P | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99783329; called by muse, varscan2
- GLI1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760192848, COSV99954799; called by muse, mutect2, varscan2
- GPATCH2L | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.28); catalogued as COSV99833977; called by muse, mutect2, varscan2
- GRIA2 | c.1492G>C p.A498P | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99646179; called by muse, mutect2, varscan2
- HCN1 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57520832, COSV57526723; called by muse, mutect2, varscan2
- HNRNPUL1 | c.538G>T p.G180* | Nonsense Mutation (SNP) | VAF 41/263 reads (16%) | catalogued as COSV54566145, COSV99647685; called by muse, mutect2, varscan2
- HOXB3 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1470917092, COSV100290851, COSV57485850; called by muse, mutect2, varscan2
- HRG | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV99215088, COSV99215163; called by muse, mutect2, varscan2
- HRNR | c.702C>A p.H234Q | Missense Mutation (SNP) | VAF 184/457 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100914032; called by muse, mutect2, varscan2
- HTRA4 | c.1004G>C p.G335A | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100206016, COSV56761444; called by muse, varscan2
- HUWE1 | c.4223G>T p.R1408L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV53346175; called by muse, mutect2
- IGLL1 | c.323-1G>T p.X108_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99968716; called by muse, mutect2
- IGSF8 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV100081865; called by muse, mutect2, varscan2
- KCNA6 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1360420986, COSV99769069; called by muse, mutect2, varscan2
- KCNH7 | c.2242G>T p.G748W | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59784904; called by muse, mutect2, varscan2
- KIF4A | c.3674C>A p.S1225Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as COSV99056454; called by muse, mutect2, varscan2
- KRTAP4-5 | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100576855; called by muse, mutect2, varscan2
- L3MBTL3 | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV100696458; called by muse, varscan2
- LILRB1 | c.368C>A p.S123Y (on ENST00000427581; = p.S87Y on NM_006669.6) | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.061); catalogued as COSV100208015; called by muse, mutect2, varscan2
- LONRF3 | c.1839G>T p.E613D (on ENST00000371628 / NM_001031855.3; = p.E572D on NM_024778.5) | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100504748; called by muse, mutect2, varscan2
- LRP5 | c.3863A>T p.D1288V | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99592786; called by muse, mutect2, varscan2
- LY75 | c.3030A>C p.L1010F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV99717157; called by muse, mutect2
- LYAR | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1299597889, COSV58642192; called by muse, mutect2, varscan2
- LYSMD2 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99591305; called by muse, mutect2, varscan2
- MAGEA6 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 33/161 reads (20%) | catalogued as COSV100263043; called by muse, mutect2, varscan2
- MARCHF1 | c.506T>A p.V169E (on ENST00000274056; = p.V152E on NM_017923.4) | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99922811; called by muse, mutect2, varscan2
- MKRN3 | c.157A>T p.R53W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100091764; called by muse, mutect2, varscan2
- MUC17 | c.7574C>T p.T2525M | Missense Mutation (SNP) | VAF 190/687 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs759930857, COSV60301125; called by muse, mutect2, varscan2
- NALCN | c.2918C>A p.P973H | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99218350; called by muse, mutect2, varscan2
- NAV3 | c.946G>C p.G316R | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV99896552; called by muse, mutect2, varscan2
- NCOR1 | c.2651G>A p.S884N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99252588; called by muse, mutect2, varscan2
- NDN | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.018); catalogued as COSV100086260; called by muse, varscan2
- NOS1AP | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.038); catalogued as COSV100723674; called by muse, mutect2, varscan2
- OR1A2 | c.424A>T p.I142F | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV101126397; called by muse, mutect2, varscan2
- OR2M4 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100141368, COSV100141577; called by muse, mutect2, varscan2
- OR4A5 | c.701T>A p.L234* | Nonsense Mutation (SNP) | VAF 18/111 reads (16%) | catalogued as COSV100157341; called by muse, mutect2, varscan2
- PAPPA2 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100867254; called by muse, mutect2, varscan2
- PCDH12 | c.2503C>A p.P835T | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99191714; called by muse, mutect2, varscan2
- PCDH17 | c.1006A>G p.K336E | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100932154; called by muse, mutect2, varscan2
- PCDH7 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1464378167; called by muse, mutect2
- PCDHGA9 | c.2171T>A p.L724Q | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as COSV99548842; called by muse, mutect2, varscan2
- PCNX2 | c.5662G>T p.G1888* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV50803020, COSV50853372; called by muse, mutect2, varscan2
- PDCL | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.043); catalogued as COSV99414243; called by muse, mutect2, varscan2
- PHIP | c.3656G>T p.R1219M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99033915; called by muse, mutect2
- PLXNB2 | c.5396A>T p.Q1799L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100834350; called by muse, mutect2, varscan2
- POMT1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100586339, COSV100586621; called by muse, mutect2, varscan2
- PSD | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.677); catalogued as COSV99194192; called by muse, mutect2
- PTCHD1 | c.1677C>G p.Y559* | Nonsense Mutation (SNP) | VAF 34/145 reads (23%) | catalogued as COSV101038052; called by muse, mutect2, varscan2
- PTPRT | c.2260C>A p.L754I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100631123; called by muse, mutect2, varscan2
- PTPRZ1 | c.3917C>A p.P1306Q | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as COSV101100924; called by muse, mutect2, varscan2
- RESF1 | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100440693; called by muse, mutect2, varscan2
- RNASE11 | c.274G>C p.G92R | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.192); catalogued as COSV100250653; called by muse, mutect2
- ROBO1 | c.2624G>T p.G875V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV101459555; called by muse, mutect2, varscan2
- RPL6 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.175); catalogued as COSV99176202; called by muse, mutect2, varscan2
- SARDH | c.822G>T p.W274C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100061342; called by muse, mutect2, varscan2
- SCN5A | c.5804G>T p.G1935V (on ENST00000333535 / NM_198056.3; = p.G1934V on NM_000335.5) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100351098; called by muse, mutect2, varscan2
- SEC24D | c.1906C>G p.L636V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99756955; called by muse, mutect2, varscan2
- SI | c.1058T>C p.L353P | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100017488; called by muse, mutect2, varscan2
- SLAMF8 | c.95C>A p.S32* | Nonsense Mutation (SNP) | VAF 43/219 reads (20%) | catalogued as COSV99223132; called by muse, mutect2, varscan2
- SLC18A1 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369004; called by muse, mutect2, varscan2
- SLC4A11 | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.993); catalogued as rs753148103, COSV101196151; called by muse, mutect2, varscan2
- SPTA1 | c.2713C>A p.L905M | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100935721; called by muse, mutect2
- STK11IP | c.1015A>T p.M339L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99823564; called by muse, mutect2, varscan2
- STRA6 | c.1684+1G>A p.X562_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as rs755941898, CS1414826, COSV99997608; called by muse, mutect2
- TG | c.2455C>A p.L819I | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV55075381, COSV99603772; called by muse, mutect2, varscan2
- TK1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750477042, COSV56745560; called by muse, mutect2, varscan2
- TNN | c.1885G>C p.D629H | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV53427696, COSV99513272; called by muse, mutect2, varscan2
- TRIM49 | c.1029G>T p.W343C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746488993, COSV100316277; called by muse, mutect2, varscan2
- TUBA3E | c.668C>A p.T223K | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as rs562742057, COSV56058788; called by muse, mutect2
- UBQLN3 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100293264; called by muse, mutect2, varscan2
- UGT1A7 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV100693331; called by muse, mutect2, varscan2
- ULK1 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100417354; called by muse, mutect2, varscan2
- UNC13C | c.3073G>T p.A1025S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV52858268, COSV99523941; called by muse, mutect2, varscan2
- VGLL3 | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as COSV101052092; called by muse, mutect2
- VPS11 | c.-58T>G | Splice Region (SNP) | VAF 33/188 reads (18%) | catalogued as COSV100334041; called by muse, mutect2, varscan2
- VPS35 | c.1955A>T p.Q652L | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100140857; called by muse, mutect2
- ZBTB32 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1380080194; called by muse, mutect2
- ZNF559 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.473); catalogued as COSV100416808, COSV57837413; called by muse, mutect2
- IGKV1-17 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2
- IGLV2-23 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 64/321 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- IL7R | c.819G>T p.W273C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNN2 | c.1285del p.E429Kfs*4 (on ENST00000264773; = p.E641Kfs*4 on NM_021614.4) | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- ZNF875 | c.1219_1224del p.H407_S408del | In Frame Del (DEL) | VAF 17/139 reads (12%) | called by mutect2, pindel, varscan2
- ACIN1 | c.1068G>A p.Q356= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99400495; called by muse, mutect2
- ADAM29 | c.432G>A p.T144= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs755566638, COSV100822299; called by muse, mutect2, varscan2
- CDHR1 | c.2163C>A p.T721= | Silent (SNP) | VAF 68/160 reads (43%) | catalogued as COSV100259440; called by muse, mutect2, varscan2
- FAM47C | c.1041C>A p.P347= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as COSV63726283; called by muse, mutect2, varscan2
- FAT1 | c.2622G>T p.T874= | Silent (SNP) | VAF 39/156 reads (25%) | catalogued as rs139157199, COSV101499678; called by muse, mutect2, varscan2
- FAT3 | c.9960T>C p.A3320= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs747834133, COSV99972112; called by muse, mutect2, varscan2
- FGF12 | c.315C>A p.L105= (on ENST00000454309 / NM_021032.5; = p.L43= on NM_004113.6) | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99284309; called by muse, mutect2, varscan2
- IFNA13 | c.264C>A p.I88= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV101489532; called by muse, mutect2, varscan2
- JAG2 | c.3423G>A p.P1141= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs138779386, COSV59310802; called by muse, mutect2, varscan2
- NSDHL | c.438C>A p.A146= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV100938699; called by muse, mutect2, varscan2
- OAS3 | c.1731C>A p.G577= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV57446069, COSV99966636; called by muse, mutect2, varscan2
- OR2H2 | c.307C>T p.L103= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV100590177; called by muse, mutect2, varscan2
- PCDH10 | c.2349C>T p.S783= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99994723; called by muse, mutect2, varscan2
- PCDHB15 | c.2028G>T p.A676= | Silent (SNP) | VAF 38/193 reads (20%) | catalogued as rs550082107, COSV50858838, COSV99179300; called by muse, mutect2, varscan2
- PCDHB8 | c.1329G>C p.S443= | Silent (SNP) | VAF 64/1096 reads (6%) | catalogued as rs61747391, COSV50791861, COSV99177545; called by muse, mutect2
- POLR2A | c.1962C>T p.H654= | Silent (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- SARS2 | c.261C>T p.P87= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99671653; called by muse, mutect2
- SLC1A5 | c.996C>T p.N332= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV101314839, COSV69467662; called by muse, mutect2, varscan2
- SLC39A4 | c.1665G>T p.V555= (on ENST00000301305 / NM_001374839.1; = p.V530= on NM_017767.3) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99433850; called by muse, mutect2
- SLC6A12 | c.285G>A p.A95= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs376674831; called by muse, mutect2, varscan2
- SPP1 | c.168C>A p.A56= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV99421278; called by muse, mutect2, varscan2
- TRPM2 | c.2091C>T p.D697= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs142650258; called by muse, mutect2, varscan2
- ZNF274 | c.1608G>T p.V536= (on ENST00000610905; = p.V431= on NM_016324.3) | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV100465636; called by muse, mutect2, varscan2
- ZXDB | c.1869G>A p.L623= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs772623039, COSV100886089; called by mutect2, varscan2
- MIR412 | n.85G>C | RNA (SNP) | VAF 12/88 reads (14%) | catalogued as rs373476147; called by muse, mutect2, varscan2
- SSPOP | n.9275G>T | RNA (SNP) | VAF 17/80 reads (21%) | catalogued as rs150092603, COSV100948203, COSV65126999; called by muse, mutect2, varscan2
